Somatic mutation profile of tumor specimen C3N-00836-02 (aliquot CPT0023810009) from CPTAC case C3N-00836, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 75.3 years (27,509 days).
Specimen C3N-00836-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96de4e6c-ead0-4c88-b477-7ab3fefe48f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00836-71 (Blood Derived Normal), aliquot CPT0023910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c0b6050-f501-4789-9ec5-32d1ae1f2bc4

The open-access MAF lists 73 somatic variants for this specimen: 55 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Nonsense Mutation 4, Intron 2, Splice Site 1, RNA 1, In Frame Del 1, 3'Flank 1, Splice Region 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.5141T>G p.V1714G | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs80357243, CM165036; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2
- ADAMTS13 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs201704847; called by muse, mutect2
- ASTN1 | c.2587G>A p.G863S | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368166205, COSV56083624; called by muse, mutect2
- C5AR1 | c.977A>G p.E326G | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs201394142; called by muse, mutect2
- CUL4A | c.1154G>A p.R385Q (on ENST00000375440 / NM_001008895.4; = p.R285Q on NM_003589.3) | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs756304466; called by muse, mutect2
- EP300 | c.4199G>A p.S1400N | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54344894; called by muse, varscan2
- FLT3LG | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143173973, COSV99201367; called by muse, mutect2
- GALNS | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.132); catalogued as rs867329892; called by muse, mutect2, varscan2
- KBTBD6 | c.1133A>G p.H378R | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs762524181; called by muse, mutect2, varscan2
- KCNK2 | c.1232C>T p.T411M (on ENST00000444842 / NM_001017425.3; = p.T396M on NM_014217.4) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as rs538085965; called by mutect2, varscan2
- LHX9 | c.762G>T p.L254F | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV61331490; called by muse, mutect2, varscan2
- MALRD1 | c.3481G>A p.A1161T | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.79); catalogued as COSV65999899; called by muse, mutect2
- MAP11 | c.1605G>A p.M535I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.022); catalogued as rs749661212; called by muse, mutect2, varscan2
- OR2Y1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs1241645003; called by muse, mutect2
- OR5M8 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59118141; called by muse, mutect2, varscan2
- PCSK2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs762323320, COSV52731184; called by muse, mutect2
- PDZD7 | c.2675_2677del p.K892del | In Frame Del (DEL) | VAF 14/150 reads (9%) | catalogued as rs397516636; called by pindel, varscan2
- STRA6 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 27/384 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs756839205; called by muse, mutect2
- ULK3 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs752274773; called by muse, mutect2, varscan2
- WARS2 | c.382T>G p.S128A | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV52479123; called by muse, mutect2
- ZNF358 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1313422387, COSV99900414; called by muse, mutect2, varscan2
- ABCC11 | c.1426T>A p.F476I | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ABCC5 | c.3419C>A p.T1140K | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- APOB | c.3036G>C p.E1012D | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2
- BMPER | c.1464T>A p.H488Q | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.312); called by muse, mutect2
- CDH23 | c.2363T>G p.V788G | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2
- CHGB | c.1103A>C p.E368A | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); called by muse, mutect2
- CHM | c.25T>G p.F9V | Missense Mutation (SNP) | VAF 29/329 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2
- CSMD3 | c.3116G>C p.G1039A (on ENST00000297405 / NM_001363185.1; = p.G935A on NM_052900.3) | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- CYFIP1 | c.3597G>A p.V1199= | Splice Region (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- DMRT2 | c.1474G>C p.V492L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH17 | c.8453G>A p.S2818N | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ELF4 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- EPHA4 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- ESYT1 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- FCRL4 | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 16/124 reads (13%) | called by mutect2, varscan2
- GABBR2 | c.1113G>C p.R371S | Missense Mutation (SNP) | VAF 73/461 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- GBP1 | c.519C>G p.S173R | Missense Mutation (SNP) | VAF 45/414 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- GRK6 | c.149-1G>A p.X50_splice | Splice Site (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- LHCGR | c.1630G>T p.A544S | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.927); called by muse, mutect2
- MED16 | c.1400T>G p.V467G | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- MKRN3 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2
- MUC6 | c.2619G>T p.E873D | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.736); called by muse, mutect2
- MYBPHL | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- NCAN | c.3365A>C p.H1122P | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- NELFCD | c.466del p.E156Nfs*3 (on ENST00000602795; = p.E138Nfs*3 on NM_198976.4) | Frame Shift Del (DEL) | VAF 37/153 reads (24%) | called by mutect2, pindel, varscan2
- OR10K2 | c.758G>C p.G253A | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- RIC3 | c.968G>A p.S323N (on ENST00000309737 / NM_001206671.4; = p.S322N on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- SYNE2 | c.15862G>T p.E5288* | Nonsense Mutation (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- TFPT | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, mutect2
- TRIM65 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSPAN10 | c.912T>A p.D304E (on ENST00000574882 / NM_001290212.1; = p.D266E on NM_031945.4) | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- USP26 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- AURKC | c.813C>G p.S271= (on ENST00000302804 / NM_001015878.2; = p.S237= on NM_003160.3) | Silent (SNP) | VAF 26/338 reads (8%) | called by muse, mutect2
- COL11A2 | c.627C>G p.A209= | Silent (SNP) | VAF 33/314 reads (11%) | called by muse, mutect2, varscan2
- CPT1A | c.1569G>T p.P523= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV55754777; called by mutect2, varscan2
- CRIM1 | c.630C>T p.C210= | Silent (SNP) | VAF 39/289 reads (13%) | called by muse, mutect2, varscan2
- FOXL2 | c.651C>G p.S217= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- HEATR5B | c.3489A>T p.R1163= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- MYH1 | c.2487G>A p.K829= | Silent (SNP) | VAF 18/168 reads (11%) | called by muse, varscan2
- PGAM2 | c.507G>A p.E169= | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- PRKAG3 | c.573C>T p.H191= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs763311884; called by muse, mutect2, varscan2
- RAP2B | c.198C>A p.S66= | Silent (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- SCN2A | c.2503T>C p.L835= | Silent (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- TBX22 | c.918C>T p.L306= | Silent (SNP) | VAF 21/335 reads (6%) | catalogued as rs767406912, COSV100961012; called by muse, mutect2
- VIRMA | c.1350C>A p.A450= | Silent (SNP) | VAF 7/184 reads (4%) | called by muse, mutect2
- GPC1 | c.167-8342G>T | Intron (SNP) | VAF 9/80 reads (11%) | catalogued as rs1328381055, COSV99882580; called by muse, mutect2, varscan2
- MPP3 | c.-29G>C | 5'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- OR11H6 | chr14:20229672 A>T | 3'Flank (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- PSG5 | c.431-2766C>T | Intron (SNP) | VAF 23/173 reads (13%) | called by muse, mutect2, varscan2
- ZNF767P | n.490A>G | RNA (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2
